Somatic mutation profile of tumor specimen TCGA-AA-A017-01A (aliquot TCGA-AA-A017-01A-01W-A00E-09) from TCGA case TCGA-AA-A017, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 57.6 years (21,032 days).
Specimen TCGA-AA-A017-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70921aad-a042-48cf-b629-9d70a4d989ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A017-10A (Blood Derived Normal), aliquot TCGA-AA-A017-10A-01W-A00E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49b90a6a-2c71-4508-b118-ef3ad944c1a0

The open-access MAF lists 53 somatic variants for this specimen: 41 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 10, Nonsense Mutation 3, Intron 2, Frame Shift Del 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3730C>T p.Q1244* | Nonsense Mutation (SNP) | VAF 124/196 reads (63%) | catalogued as rs79122263, CM010756, COSV57329765; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGD1 | c.1555C>T p.R519C | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1557189252, COSV64308969; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.475G>C p.A159P | Missense Mutation (SNP) | VAF 28/43 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730882000, COSV52661847, COSV52680639, COSV52688008, COSV52782769; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAMTS12 | c.3788C>T p.T1263M | Missense Mutation (SNP) | VAF 255/438 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs757177041, COSV100710420, COSV61263698; called by muse, mutect2, varscan2
- AGTR2 | c.118T>A p.S40T | Missense Mutation (SNP) | VAF 239/411 reads (58%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs782530337, COSV64156609; called by muse, mutect2, varscan2
- ARG1 | c.769G>A p.G257S | Missense Mutation (SNP) | VAF 140/523 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs372489226; called by muse, mutect2, varscan2
- ARID1A | c.6469G>A p.D2157N | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as COSV61380259; called by muse, mutect2, varscan2
- ARL14EP | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 4/99 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1277328395, COSV99955894; called by muse, mutect2
- ATG4C | c.586T>G p.Y196D | Missense Mutation (SNP) | VAF 89/322 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.288); catalogued as COSV58606482; called by muse, mutect2, varscan2
- ATG5 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV58348648; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.637T>A p.S213T | Missense Mutation (SNP) | VAF 70/457 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV57280391; called by muse, mutect2, varscan2
- BNC1 | c.198C>T p.H66= | Splice Region (SNP) | VAF 41/106 reads (39%) | catalogued as rs753116483, COSV61757150; called by muse, mutect2, varscan2
- CDC42BPG | c.4240G>A p.V1414M | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs139262308, COSV61346507; called by muse, mutect2, varscan2
- CNTN6 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 185/327 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV63176547; called by muse, mutect2, varscan2
- COL11A1 | c.1696G>A p.V566I | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs1251543692, COSV62185294; called by muse, mutect2, varscan2
- DDX56 | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51836906; called by muse, mutect2
- EIF4A2 | c.463_465del p.I155del | In Frame Del (DEL) | VAF 34/68 reads (50%) | catalogued as rs767682413; called by mutect2, pindel, varscan2
- FAAH2 | c.113C>G p.S38* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | catalogued as COSV66508901; called by muse, mutect2, varscan2
- FREM2 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs533045176, COSV54827471; called by muse, mutect2, varscan2
- GABRA5 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as COSV59475659; called by muse, mutect2, varscan2
- ISCU | c.214G>A p.V72I (on ENST00000311893 / NM_213595.4; = p.V47I on NM_014301.4) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.88); catalogued as rs914914914, COSV57208143; called by muse, mutect2, varscan2
- KEL | c.1963C>T p.R655W | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs370938244, COSV62335275; called by muse, mutect2, varscan2
- LAMA1 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200844421, COSV67539030; called by muse, mutect2, varscan2
- LAMC1 | c.2752G>T p.A918S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.011); catalogued as COSV51148147; called by muse, mutect2, varscan2
- LILRA4 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.995); catalogued as rs144792088; called by muse, mutect2, varscan2
- MORN3 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.89); catalogued as COSV62507505; called by muse, mutect2, varscan2
- NBEA | c.5362G>A p.D1788N | Missense Mutation (SNP) | VAF 31/289 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV59794663; called by muse, varscan2
- NPR3 | c.1544G>A p.R515Q (on ENST00000265074 / NM_001364458.2; = p.R514Q on NM_000908.4) | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs201694177, COSV54089023; called by muse, mutect2, varscan2
- OR13F1 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs138205504; called by muse, mutect2, varscan2
- OR8J1 | c.629C>A p.S210Y | Missense Mutation (SNP) | VAF 109/466 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57318825; called by muse, mutect2, varscan2
- PCDH10 | c.1997C>T p.P666L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52087077, COSV52090963; called by muse, mutect2, varscan2
- PKDREJ | c.4462G>A p.E1488K | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs773210842, COSV53550030; called by muse, mutect2, varscan2
- SCML4 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs748183780, COSV64636209; called by muse, mutect2, varscan2
- SMC6 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61178372; called by muse, mutect2
- STON1 | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs147440328, COSV100562377; called by muse, mutect2, varscan2
- TPO | c.2728G>A p.A910T | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.012); catalogued as rs750068617, COSV61094907; called by muse, varscan2
- TTC22 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1389860349, COSV64881564; called by muse, mutect2
- TUT7 | c.355G>C p.G119R | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.365); catalogued as COSV52896480; called by muse, mutect2, varscan2
- UMOD | c.1633C>A p.Q545K | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.141); catalogued as COSV56776655; called by muse, mutect2, varscan2
- SLITRK3 | c.279_280del p.T94Qfs*8 | Frame Shift Del (DEL) | VAF 94/207 reads (45%) | called by pindel, varscan2
- UBE2NL | c.175C>G p.L59V | Missense Mutation (SNP) | VAF 83/289 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ADGRD1 | c.1530C>T p.C510= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as rs149379586; called by muse, mutect2, varscan2
- HECW1 | c.3888G>A p.S1296= | Silent (SNP) | VAF 57/201 reads (28%) | catalogued as rs764833849, COSV67832225; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1591C>T p.L531= | Silent (SNP) | VAF 184/348 reads (53%) | catalogued as COSV61163250; called by muse, mutect2, varscan2
- MED14 | c.2277T>A p.G759= | Silent (SNP) | VAF 8/184 reads (4%) | catalogued as COSV100247411; called by muse, mutect2
- NOVA1 | c.288T>G p.T96= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV57479803; called by muse, mutect2, varscan2
- PACS1 | c.1329T>C p.T443= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV57698250; called by muse, mutect2, varscan2
- SEPTIN12 | c.339G>A p.T113= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs944969696, COSV51617637; called by muse, mutect2
- SLC6A15 | c.306A>C p.P102= | Silent (SNP) | VAF 34/134 reads (25%) | catalogued as COSV57025220; called by muse, mutect2, varscan2
- SPHKAP | c.3216C>T p.G1072= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs746620324, COSV60883316; called by muse, mutect2, varscan2
- ZNF526 | c.1587A>G p.Q529= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV55899743; called by muse, mutect2, varscan2
- PXN | c.831+2233G>A | Intron (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- SCARB1 | c.1651+3368G>A | Intron (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99909099; called by muse, mutect2, varscan2
